CPTAC case C3L-02616 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b27d0ac1-393b-4232-aefa-15e505569fd6

Demographics
Sex at birth: male; Race: white; Year of birth: 1954; Vital status: Dead; Days to death: 244 days; Year of death: 2018; Cause of death: Cancer Related; Country of birth: Bulgaria.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Middle lobe, lung; Age at diagnosis: 63.7 years (23,275 days); Year of diagnosis: 2018; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T2a; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 244 days; Days to last follow up: 8 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.3 cm (a second GDC size field records 3.2 cm); Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 20; Margin status: Uninvolved.

Follow-up (1 entry)
- Days to follow up: 8 days; Disease response: With Tumor.

Other clinical attributes
- Weight: 80 kg; Height: 177 cm; BMI: 25.54.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Cigarettes per day: 20; Tobacco smoking quit year: 2010; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02616-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 535 mg; Time between clamping and freezing: 33 minutes; Time between excision and freezing: 18 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02616-25: Section location: Right Middle Lobe; Percent tumor nuclei: 85; Percent necrosis: 3.
- Sample C3L-02616-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 144 mg; Time between clamping and freezing: 36 minutes; Time between excision and freezing: 21 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02616-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
